Somatic mutation profile of tumor specimen C3L-01149-01 (aliquot CPT0218770006) from CPTAC case C3L-01149, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,725 days).
Specimen C3L-01149-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c09720c-2aeb-4a9c-ade5-ae675761bf71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01149-31 (Blood Derived Normal), aliquot CPT0220350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65ed567b-992b-4a4e-8d93-7ca460c4b0d2

The open-access MAF lists 72 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Intron 9, Nonsense Mutation 4, Splice Site 3, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1499-2A>T p.X500_splice | Splice Site (SNP) | VAF 67/72 reads (93%) | hotspot (GDC flag); catalogued as rs1258442224, CS016049, CS083259, COSV57297794, COSV57328330, COSV57333571; called by muse, mutect2, varscan2
- AC013489.1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as rs367738496; called by muse, mutect2, varscan2
- AGO2 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760059271, COSV55047468; called by muse, mutect2, varscan2
- CD163L1 | c.2163G>T p.M721I | Missense Mutation (SNP) | VAF 135/145 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746808608, COSV58023836; called by muse, mutect2, varscan2
- CD209 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs374114895; called by muse, mutect2, varscan2
- FYCO1 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs543095427; called by muse, mutect2, varscan2
- HS3ST3A1 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV52375471; called by mutect2, varscan2
- HS3ST3B1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs761879291, COSV62906562; called by muse, mutect2, varscan2
- KCNH5 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750874924, COSV59752526; called by muse, mutect2, varscan2
- LYG1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 111/212 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781033742, COSV57915725; called by muse, mutect2, varscan2
- MRPL49 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 182/373 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.343); catalogued as rs758327244; called by muse, mutect2, varscan2
- MTHFR | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV57172912; called by muse, mutect2, varscan2
- NAPG | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100529948; called by muse, mutect2, varscan2
- NDST2 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 105/110 reads (95%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs141599100; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5K3 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV67350322; called by muse, mutect2, varscan2
- PGPEP1 | c.537C>G p.D179E | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV53252136; called by muse, mutect2
- SLC26A5 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs772447046; called by muse, mutect2, varscan2
- SLC9A4 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 27/60 reads (45%) | catalogued as rs754266683, COSV54829700; called by muse, mutect2, varscan2
- TENM3 | c.5002C>T p.R1668* | Nonsense Mutation (SNP) | VAF 54/138 reads (39%) | catalogued as rs1426216066; called by muse, mutect2, varscan2
- TNRC6C | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs781193694, COSV56942630; called by muse, mutect2, varscan2
- WHRN | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs1311654091; called by muse, mutect2, varscan2
- ZFP42 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200711766, COSV58816789; called by muse, mutect2, varscan2
- BORCS6 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); called by muse, mutect2
- C17orf78 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CCDC148 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CEACAM21 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CTAGE8 | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 97/998 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX15 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DYNC1I1 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- FAT4 | c.7556C>A p.P2519Q | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2
- FBXO34 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FUT4 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 197/479 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GDA | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HBM | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 240/545 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- IFNGR1 | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- IGSF3 | c.1094A>C p.H365P | Missense Mutation (SNP) | VAF 150/170 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ITGA2 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ITPRID1 | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LAIR1 | c.770G>A p.W257* | Nonsense Mutation (SNP) | VAF 79/151 reads (52%) | called by muse, mutect2, varscan2
- NLRP3 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 173/251 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- OR4P4 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); called by muse, varscan2
- STEAP1B | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TIMELESS | c.2037G>C p.L679F | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); called by muse, varscan2
- TIMELESS | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 62/158 reads (39%) | called by muse, varscan2
- TOP2B | c.4489+1G>A p.X1497_splice (on ENST00000264331 / NM_001330700.2; = p.X1492_splice on NM_001068.3) | Splice Site (SNP) | VAF 60/110 reads (55%) | called by muse, mutect2, varscan2
- TUSC3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ZMYM1 | c.1979C>G p.S660* | Nonsense Mutation (SNP) | VAF 84/137 reads (61%) | called by muse, mutect2, varscan2
- CCSER2 | c.903G>A p.L301= | Silent (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- CRTC1 | c.792C>T p.P264= | Silent (SNP) | VAF 30/288 reads (10%) | catalogued as rs779704646; called by muse, mutect2, varscan2
- MAGEB3 | c.906G>A p.A302= | Silent (SNP) | VAF 96/96 reads (100%) | catalogued as COSV64397375; called by muse, mutect2, varscan2
- MICALL2 | c.2196C>T p.P732= | Silent (SNP) | VAF 107/353 reads (30%) | catalogued as rs61731571; called by muse, mutect2, varscan2
- OR1F1 | c.321C>T p.F107= | Silent (SNP) | VAF 122/303 reads (40%) | catalogued as rs375366387; called by muse, mutect2, varscan2
- PALM | c.942C>T p.T314= | Silent (SNP) | VAF 199/391 reads (51%) | called by muse, mutect2, varscan2
- PTPN21 | c.3513C>G p.S1171= | Silent (SNP) | VAF 136/293 reads (46%) | called by muse, mutect2, varscan2
- PWP1 | c.402T>C p.D134= | Silent (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- SPEM1 | c.588C>T p.S196= | Silent (SNP) | VAF 100/257 reads (39%) | catalogued as rs377566043; called by muse, mutect2, varscan2
- ST14 | c.2391C>T p.G797= | Silent (SNP) | VAF 134/274 reads (49%) | called by muse, mutect2, varscan2
- TMEM132C | c.3189C>T p.P1063= | Silent (SNP) | VAF 81/159 reads (51%) | called by muse, mutect2, varscan2
- TRAF3IP3 | c.438T>G p.A146= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- CARF | c.-97G>C | 5'UTR (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- CCSER1 | c.2094+23066C>T | Intron (SNP) | VAF 78/183 reads (43%) | catalogued as rs753404872, COSV61406023; called by muse, mutect2, varscan2
- CEROX1 | n.2785G>A | RNA (SNP) | VAF 146/318 reads (46%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8637+74_8637+75del | Intron (DEL) | VAF 95/259 reads (37%) | called by mutect2, pindel, varscan2
- HBS1L | c.430+1921G>A | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+781G>T | Intron (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- MCAM | c.560-28A>G | Intron (SNP) | VAF 52/105 reads (50%) | catalogued as rs1320476132; called by muse, mutect2, varscan2
- NCDN | c.-36+13C>T | Intron (SNP) | VAF 42/115 reads (37%) | catalogued as rs1187374890; called by muse, mutect2, varscan2
- NEU4 | c.-4+63T>A | Intron (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- POLR2J3 | c.140+16C>G | Intron (SNP) | VAF 62/424 reads (15%) | called by mutect2, varscan2
- POLR2J3 | c.-13C>T | 5'UTR (SNP) | VAF 128/739 reads (17%) | catalogued as rs761170627; called by muse, mutect2, varscan2
- UBE2J2 | c.172+25_172+27del | Intron (DEL) | VAF 46/107 reads (43%) | catalogued as rs1557559166; called by pindel, varscan2
